Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6536, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6536-01A (Primary Tumor).

[REDACTED]

Examination: Histopathological examination

[REDACTED] TCGA - D5 - 6536

[REDACTED]

Material: 1. Multiple organ resection – sigmoid colon with rectum and two tumours

[REDACTED]

Physician in charge: [REDACTED]

Material collected on [REDACTED] Material received on [REDACTED]

Expected time of examination [REDACTED]

Clinical diagnosis: Bi-focal cancer of the large intestine (sigmoid colon and rectum) SPECIMEN - sigmoid colon with rectum and two tumours. Proximal end marked with wire.

[REDACTED]

Examination performed on: [REDACTED]

Macroscopic description:

A 32 cm length of intestine with fat tissue sized 32 x 6 x 2 cm. A cauliflower-shaped tumour sized 5 x 3 x 2.5 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference, narrowing its lumen; removed 10 cm from the proximal incision and 11 cm from the distal incision. The lesion penetrates macroscopically the intestine wall and the fat tissue. Minimum side margin is 1.1 cm.

A second tumour seized 2.5 x 3 x 1 cm located 5 cm away from the first one, removed 22 cm from the proximal boundary and 3 cm from the distal one. The tumour penetrates the intestinal wall; side margin 2.5 cm.

Microscopic description:

Adenocarcinoma tubulopapillare partim mucinosum (G3).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae

Minimum side margin is 1.1 cm. Intestine ends free of neoplastic lesions.

Outside tumour 1: Adenocarcinoma tubulopapillare G1. Infiltratio carcinomatosa tunicae muscularis propriae et adiposae pericolicae.

Lymphonodulitis reactiva lymphonodorum (No XIV).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare partim musinosum coli bifocale. Tubulopapillar and partially mucinous bifocal adenocarcinoma of the colon. (G3, Dukes B, Astler - Collier B2, pT3, pNO).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file aa7ba8b5-64dd-4f25-a193-afa878798a13 (TCGA-D5-6536.6C5CF659-1DEA-4BA4-8E62-9CF19384F72A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).